MMRF case MMRF_1458 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/74dad290-72fd-4b1f-9ae3-0407897d937b

Demographics
Sex at birth: male; Age at index: 79 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 79.2 years (28,926 days); ISS stage: III; Days to last known disease status: 1,382 days (3.8 years); Days to last follow up: 1,382 days (3.8 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 130 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 130 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 233 days; Days to treatment end: 641 days (1.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 233 days; Days to treatment end: 540 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide + Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,342 days (3.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,382.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 1): M Protein 2.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 186 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 26.1 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 7.3 µg/mL; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.38 mmol/L; Albumin 26 g/L; Total Protein 8.3 g/dL; Glucose 4.57 mmol/L; C-Reactive Protein 0.31 mg/dL.
- Day 92 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 3.5 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 9.5 ×10⁹/L; Platelets 368 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 5.61 mmol/L.
- Day 269 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 5.11 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 13.8 ×10⁹/L; Absolute Neutrophil 9.9 ×10⁹/L; Platelets 324 ×10⁹/L; Creatinine 148 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 5.2 g/dL; Glucose 4.84 mmol/L.
- Day 372 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 3.19 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 5.5 g/dL; Glucose 5.17 mmol/L.
- Day 471 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 2.89 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 7.1 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 5.5 g/dL; Glucose 6.55 mmol/L.
- Day 540 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 2.78 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 4.71 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 52 ×10⁹/L; Creatinine 189 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 5.5 g/dL; Glucose 5.23 mmol/L.
- Day 625 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 4.74 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 48 ×10⁹/L; Creatinine 189 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 5.06 mmol/L.
- Day 737 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.24 mg/dL; Immunoglobulin G 7.58 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 172 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.35 mmol/L; Albumin 31 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 807 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.22 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 1.52 g/L; Immunoglobulin M 0.57 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 200 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 4.62 mmol/L.
- Day 891: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.73 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 1.69 g/L; Immunoglobulin M 0.6 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 174 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 4.46 mmol/L.
- Day 974: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.81 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.76 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 167 µmol/L; Blood Urea Nitrogen 15.4 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 5.56 mmol/L.
- Day 1,108 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.58 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 2.66 g/L; Immunoglobulin M 0.68 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 16.1 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 5.28 mmol/L.
- Day 1,214 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.21 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 2.51 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 188 µmol/L; Blood Urea Nitrogen 17.5 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 4.29 mmol/L.
- Day 1,339 (ECOG 1): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 65.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 19.4 g/L; Immunoglobulin A 1.77 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 162 µmol/L; Blood Urea Nitrogen 18.9 mmol/L; Calcium 2.3 mmol/L; Albumin 29 g/L; Total Protein 7.3 g/dL; Glucose 5.06 mmol/L.
- Day 1,381 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.49 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 185 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.15 mmol/L; Albumin 29 g/L; Total Protein 7 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -10: Weight: 77 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (1 sample)
- Sample MMRF_1458_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
